Somatic mutation profile of tumor specimen TCGA-EJ-5527-01A (aliquot TCGA-EJ-5527-01A-01D-1576-08) from TCGA case TCGA-EJ-5527, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.1 years (25,234 days).
Specimen TCGA-EJ-5527-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88ded295-5666-4aad-aa7d-f033d55e12b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5527-10A (Blood Derived Normal), aliquot TCGA-EJ-5527-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6aafa28c-6463-49fc-839a-a3619c1b8848

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 14, Silent 11, Frame Shift Del 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3248T>C p.V1083A | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV64678932; called by muse, mutect2
- CCNYL1 | c.1020_1022del p.R341del (on ENST00000295414 / NM_001330218.2; = p.R271del on NM_152523.2) | In Frame Del (DEL) | VAF 57/381 reads (15%) | catalogued as rs778809180; called by mutect2, pindel, varscan2
- CDC42BPB | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV63477163; called by muse, mutect2
- CHP1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs867542118, COSV58158622; called by muse, mutect2, varscan2
- FCRL4 | c.307+1G>C p.X103_splice | Splice Site (SNP) | VAF 19/182 reads (10%) | catalogued as COSV54866994, COSV99619078; called by muse, mutect2, varscan2
- GRIK4 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771623867, COSV70805576; called by mutect2, varscan2
- HAVCR1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 74/581 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.751); catalogued as rs1334343322, COSV59403867; called by muse, mutect2, varscan2
- KIF21B | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV59767923; called by muse, mutect2, varscan2
- MAL | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752335452, COSV59432980; called by muse, mutect2, varscan2
- PLA2G2A | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.442); catalogued as COSV64287695; called by muse, mutect2, varscan2
- SLC22A7 | c.1192C>T p.R398C (on ENST00000372585 / NM_153320.2; = p.R396C on NM_006672.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs891750270, COSV51486402; called by muse, mutect2
- SPART | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 45/350 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62088910; called by muse, mutect2, varscan2
- TP53TG5 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs781269723, COSV65576972, COSV65578106; called by muse, mutect2, varscan2
- TRIP12 | c.3767A>G p.Q1256R | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV52273771; called by muse, mutect2, varscan2
- ZNF516 | c.3023A>T p.Q1008L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV71587721; called by muse, mutect2, varscan2
- ZNF778 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.404); catalogued as COSV60603079; called by muse, mutect2
- SLITRK4 | c.1180_1182delinsTT p.V394Ffs*15 | Frame Shift Del (DEL) | VAF 84/320 reads (26%) | called by pindel, varscan2*
- SURF4 | c.511del p.T171Pfs*21 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- UBFD1 | c.645_646insAG p.V216Rfs*15 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, pindel
- ADRB2 | c.957T>G p.S319= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV60006406; called by muse, mutect2
- ALDH3A2 | c.552G>A p.T184= | Silent (SNP) | VAF 35/218 reads (16%) | catalogued as rs904950394, COSV51569088; called by muse, mutect2, varscan2
- ARAP2 | c.3511A>C p.R1171= | Silent (SNP) | VAF 13/208 reads (6%) | catalogued as COSV58293374; called by muse, mutect2
- BCOR | c.4656T>C p.Y1552= (on ENST00000378444 / NM_001123385.2; = p.Y1518= on NM_017745.6) | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1444202077, COSV60716029, COSV60720158; called by muse, mutect2
- DPY19L2 | c.1668A>G p.L556= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV61046844; called by muse, mutect2, varscan2
- GRM3 | c.1530C>T p.S510= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as rs527768281, COSV64480613; called by muse, mutect2, varscan2
- LRRFIP2 | c.1186T>C p.L396= | Silent (SNP) | VAF 60/284 reads (21%) | catalogued as COSV60870910; called by muse, mutect2, varscan2
- OXSM | c.493T>C p.L165= | Silent (SNP) | VAF 34/342 reads (10%) | catalogued as COSV55002828; called by muse, mutect2
- TCF20 | c.417T>C p.F139= | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as COSV59496665; called by muse, mutect2, varscan2
- TRIM9 | c.2064C>T p.N688= | Silent (SNP) | VAF 70/283 reads (25%) | catalogued as rs780667250, COSV53625732; called by muse, mutect2, varscan2
- XIRP2 | c.855T>G p.L285= (on ENST00000628543; = p.L460= on NM_152381.6) | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as COSV54738273; called by muse, mutect2, varscan2
